Somatic mutation profile of tumor specimen MP2PRT-PATLJH-TMP1-A (aliquot MP2PRT-PATLJH-TMP1-A-3-0-D-A79Q-36) from MP2PRT case MP2PRT-PATLJH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (783 days).
Specimen MP2PRT-PATLJH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 245313c6-6b77-462a-8c9d-07b86e91e1d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLJH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLJH-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b460dce-2a49-4d95-8a74-5cabdfc21630

The open-access MAF lists 105 somatic variants for this specimen: 78 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 23, Translation Start Site 1, Splice Region 1, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, RNA 1, Nonstop Mutation 1, Splice Site 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.4362C>G p.F1454L | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV54950478; called by muse, mutect2
- ADRA1B | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.368); catalogued as rs1190964921; called by muse, mutect2, varscan2
- ANAPC2 | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 14/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs907354773; called by muse, mutect2
- ANK1 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55879004; called by muse, mutect2, varscan2
- ARHGAP28 | c.1249G>A p.E417K (on ENST00000383472 / NM_001366230.1; = p.E258K on NM_001010000.3) | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51631395; called by muse, mutect2, varscan2
- ATF6B | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 20/684 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV64352034; called by muse, mutect2
- ATM | c.7487G>C p.G2496A | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs764478418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 17/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66579497; called by muse, mutect2
- C7 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280293403; called by muse, varscan2
- CAMK2D | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV99594178; called by muse, mutect2, varscan2
- CCDC102B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs199750681; called by muse, mutect2, varscan2
- CDH10 | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV52577618, COSV52579065; called by muse, mutect2
- CTTNBP2 | c.2699T>G p.V900G | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV99353727; called by muse, mutect2
- DLC1 | c.3242C>T p.T1081M (on ENST00000276297 / NM_001348081.2; = p.T644M on NM_006094.5) | Missense Mutation (SNP) | VAF 145/384 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs752787691; called by muse, mutect2, varscan2
- EPB41L3 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 121/340 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.444); catalogued as rs746460874; called by muse, mutect2, varscan2
- FREM2 | c.5899G>A p.D1967N | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54838168; called by muse, mutect2, varscan2
- FYB1 | c.1620C>G p.I540M | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100685019; called by muse, mutect2
- GRIA4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 49/533 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.063); catalogued as COSV56882288, COSV99031207; called by muse, mutect2
- NKX2-3 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.32); catalogued as rs373715351; called by muse, mutect2, varscan2
- OSBPL6 | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV99507360; called by muse, mutect2
- PAX5 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM1514451, COSV63906029; called by muse, mutect2
- PCDH8 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 264/666 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs1354217238, COSV58811597; called by muse, mutect2, varscan2
- PCDHA7 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 82/473 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV100971745; called by muse, mutect2, varscan2
- PDE4DIP | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288801467, COSV100519774, COSV57718114; called by muse, mutect2
- PHF3 | c.2105C>G p.S702C | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1314971021, COSV50364673; called by muse, mutect2
- RBMXL3 | c.2798C>G p.S933C | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV100406777; called by muse, mutect2, varscan2
- SLC10A6 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 10/241 reads (4%) | catalogued as COSV99907295; called by muse, mutect2
- SORCS1 | c.2473G>C p.E825Q | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.758); catalogued as COSV53864707; called by muse, mutect2, varscan2
- TADA1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1486859949; called by muse, mutect2
- TLR5 | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60560958; called by muse, mutect2
- TMEM132D | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67161304; called by muse, mutect2
- UGT2B28 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 147/187 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs748410262; called by muse, mutect2, varscan2
- ZIC3 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as CM140977; called by muse, mutect2
- ZMPSTE24 | c.17C>G p.S6W | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV65639406, COSV65640266; called by muse, mutect2, varscan2
- ZNF772 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100582772; called by muse, mutect2
- ACP3 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALPI | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP22 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2
- CCDC88A | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPS1 | c.4135G>C p.E1379Q | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRAMP1 | c.3223C>G p.L1075V | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DBF4 | c.2025G>C p.*675Yext*20 | Nonstop Mutation (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- DZIP1 | c.1883G>C p.G628A (on ENST00000347108; = p.G609A on NM_014934.5) | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EIF2AK3 | c.2989C>G p.H997D | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.053); called by muse, mutect2
- EVI5 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM178B | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/276 reads (4%) | SIFT tolerated, low confidence (0.14); called by muse, mutect2
- FRAS1 | c.5407G>C p.D1803H | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HORMAD1 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IGHV3-30 | c.348_349insGGC p.A116_K117insG | In Frame Ins (INS) | VAF 32/74 reads (43%) | called by pindel, varscan2
- LOXHD1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 127/321 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K19 | c.316C>T p.L106= | Splice Region (SNP) | VAF 10/225 reads (4%) | called by muse, mutect2
- MARCKS | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 123/528 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- MED17 | c.418-1G>C p.X140_splice | Splice Site (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- MED31 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 6/170 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.122); called by muse, mutect2
- MPDZ | c.4247C>T p.S1416L | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NAALADL1 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NPL | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRG3 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 15/573 reads (3%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.938); called by muse, mutect2
- OR4D1 | c.612dup p.L205Afs*111 | Frame Shift Ins (INS) | VAF 101/349 reads (29%) | called by mutect2, pindel, varscan2
- OTUD6A | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- PDC | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PSG3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 152/402 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RAPGEF4 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RPE65 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RPGR | c.1209G>C p.Q403H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2
- RUNX1T1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.009); called by muse, mutect2
- SNTG1 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SOD3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 186/467 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SVEP1 | c.7796C>T p.S2599L | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBC1D12 | c.1992G>C p.L664F | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- TCERG1 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRIM64B | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- TRPC3 | c.1063G>C p.E355Q (on ENST00000379645 / NM_001366479.2; = p.E282Q on NM_003305.2) | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- TTC12 | c.1113G>C p.E371D | Missense Mutation (SNP) | VAF 16/516 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- ZNF722P | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ZNF808 | c.2612G>C p.G871A | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ANK3 | c.1062C>G p.L354= | Silent (SNP) | VAF 105/433 reads (24%) | catalogued as rs769360600; called by muse, mutect2, varscan2
- ATP4A | c.2406C>G p.L802= | Silent (SNP) | VAF 131/322 reads (41%) | called by muse, mutect2, varscan2
- BIN2 | c.1617C>G p.V539= | Silent (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- CCN3 | c.627G>A p.Q209= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- DYNC2I1 | c.54C>T p.L18= | Silent (SNP) | VAF 58/211 reads (27%) | catalogued as COSV101237836; called by muse, mutect2, varscan2
- FA2H | c.108C>G p.L36= | Silent (SNP) | VAF 88/708 reads (12%) | called by muse, mutect2, varscan2
- FBH1 | c.2427C>T p.I809= (on ENST00000362091 / NM_178150.3; = p.I860= on NM_032807.4) | Silent (SNP) | VAF 27/312 reads (9%) | catalogued as COSV100758826; called by muse, mutect2
- GPR149 | c.126C>G p.L42= | Silent (SNP) | VAF 39/269 reads (14%) | called by muse, mutect2, varscan2
- GPR17 | c.699C>T p.F233= | Silent (SNP) | VAF 225/522 reads (43%) | called by muse, mutect2, varscan2
- GRIA4 | c.216G>A p.E72= | Silent (SNP) | VAF 49/523 reads (9%) | called by muse, mutect2
- IGHV3-21 | c.144C>T p.F48= | Silent (SNP) | VAF 115/313 reads (37%) | catalogued as rs782353884; called by muse, varscan2
- LRFN3 | c.135C>T p.C45= | Silent (SNP) | VAF 47/732 reads (6%) | called by muse, mutect2
- MAP2 | c.4374G>A p.V1458= | Silent (SNP) | VAF 9/189 reads (5%) | catalogued as rs1293264248; called by muse, mutect2
- MTPAP | c.945C>T p.F315= | Silent (SNP) | VAF 17/398 reads (4%) | called by muse, mutect2
- MTUS2 | c.1944C>T p.I648= | Silent (SNP) | VAF 17/595 reads (3%) | catalogued as COSV70918053; called by muse, mutect2
- NBEAL2 | c.6591G>A p.S2197= | Silent (SNP) | VAF 90/391 reads (23%) | catalogued as rs554449998; called by muse, mutect2, varscan2
- OLFML2B | c.2100C>T p.F700= | Silent (SNP) | VAF 81/247 reads (33%) | catalogued as rs774895563, COSV54196024; called by muse, mutect2, varscan2
- OR6B2 | c.312C>T p.F104= | Silent (SNP) | VAF 85/289 reads (29%) | catalogued as rs1245651025; called by muse, mutect2, varscan2
- RAD54L | c.471G>A p.Q157= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as rs1373773358, COSV64336493; called by muse, mutect2
- RECQL4 | c.2187C>G p.V729= | Silent (SNP) | VAF 61/327 reads (19%) | called by muse, mutect2, varscan2
- SPON2 | c.72C>T p.A24= | Silent (SNP) | VAF 20/566 reads (4%) | catalogued as rs979955323; called by muse, mutect2
- TMEM165 | c.930G>A p.A310= | Silent (SNP) | VAF 48/235 reads (20%) | catalogued as rs368593849; called by muse, mutect2, varscan2
- TRPM3 | c.507C>G p.L169= (on ENST00000357533 / NM_001366142.2; = p.L14= on NM_020952.6) | Silent (SNP) | VAF 60/278 reads (22%) | called by muse, mutect2, varscan2
- AL138999.2 | chr13:33350362 C>T | 3'Flank (SNP) | VAF 124/349 reads (36%) | called by muse, mutect2, varscan2
- LINC01844 | n.523C>G | RNA (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- PIK3R1 | c.-189G>A | 5'UTR (SNP) | VAF 15/237 reads (6%) | called by muse, mutect2
- UVSSA | c.*9120C>G | 3'UTR (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
